Somatic mutation profile of tumor specimen C3L-03639-01 (aliquot CPT0238610012) from CPTAC case C3L-03639, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 76.0 years (27,761 days).
Specimen C3L-03639-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7722a037-7a7e-49b9-8f9b-9c12170b7acf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-03639-31 (Blood Derived Normal), aliquot CPT0238650002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/32c250f0-500c-4982-b397-eb6d837bef85

The open-access MAF lists 100 somatic variants for this specimen: 79 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 68, Silent 14, Nonsense Mutation 4, Frame Shift Ins 3, RNA 2, Intron 2, 3'Flank 1, 5'UTR 1, 3'UTR 1, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL7A1 | c.5314C>T p.R1772W | Missense Mutation (SNP) | VAF 203/984 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1032335328, CM992843; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 183/412 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- A4GNT | c.893G>A p.R298Q | Missense Mutation (SNP) | VAF 104/620 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.439); catalogued as rs771025283, COSV52629476; called by muse, mutect2, varscan2
- AC100868.1 | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 11/77 reads (14%) | catalogued as rs34597028; called by muse, mutect2, varscan2
- ATP1A2 | c.1244C>T p.T415M | Missense Mutation (SNP) | VAF 118/1026 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121918618, CM072871, COSV63406206; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BMS1 | c.1106C>T p.T369I | Missense Mutation (SNP) | VAF 61/355 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.02); catalogued as rs1390840803; called by muse, mutect2, varscan2
- C20orf96 | c.353G>A p.R118H (on ENST00000360321 / NM_153269.3; = p.R117H on NM_080571.1) | Missense Mutation (SNP) | VAF 107/745 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754475212; called by muse, mutect2, varscan2
- CDH10 | c.2144A>C p.N715T | Missense Mutation (SNP) | VAF 42/444 reads (9%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.589); catalogued as COSV52583849; called by muse, mutect2
- CDH11 | c.82C>T p.R28W | Missense Mutation (SNP) | VAF 84/396 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs779648442; called by muse, mutect2, varscan2
- EEF1AKNMT | c.2084C>T p.T695M (on ENST00000361735 / NM_015935.5; = p.T609M on NM_014955.3) | Missense Mutation (SNP) | VAF 40/336 reads (12%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs575314244, COSV62283000; called by muse, mutect2, varscan2
- FGFR1 | c.787G>A p.A263T (on ENST00000447712 / NM_023110.3; = p.A261T on NM_015850.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/150 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.967); catalogued as rs747978107, COSV58332859; ClinVar: likely benign / benign / uncertain significance; called by muse, mutect2, varscan2
- FSTL4 | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 97/530 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as rs201737601; called by muse, mutect2, varscan2
- GFOD1 | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 111/797 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs757177243, COSV64954512; called by muse, mutect2, varscan2
- GRIK2 | c.2692G>A p.D898N | Missense Mutation (SNP) | VAF 90/225 reads (40%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.155); catalogued as rs751533944, COSV59729088; called by muse, mutect2, varscan2
- KCNH1 | c.1483T>G p.F495V (on ENST00000271751 / NM_172362.3; = p.F468V on NM_002238.4) | Missense Mutation (SNP) | VAF 44/401 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55068201; called by muse, mutect2, varscan2
- KIT | c.482G>T p.R161M | Missense Mutation (SNP) | VAF 125/556 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV55423622; called by muse, mutect2, varscan2
- LAMB4 | c.2098G>A p.A700T | Missense Mutation (SNP) | VAF 53/341 reads (16%) | SIFT tolerated (0.33); PolyPhen benign (0.003); catalogued as rs754196717, COSV52717261, COSV52726584; called by muse, mutect2, varscan2
- LRFN1 | c.2230G>T p.G744W | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.431); catalogued as COSV50455441; called by muse, mutect2
- MICALL2 | c.1144C>T p.P382S | Missense Mutation (SNP) | VAF 56/215 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.112); catalogued as rs774800327, COSV52518203; called by muse, mutect2, varscan2
- MROH2A | c.2024C>T p.A675V | Missense Mutation (SNP) | VAF 42/468 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs1056895420; called by muse, mutect2
- NALCN | c.4403G>A p.R1468H | Missense Mutation (SNP) | VAF 47/342 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.479); catalogued as COSV51916921; called by muse, mutect2, varscan2
- NUP62 | c.1519G>A p.E507K | Missense Mutation (SNP) | VAF 80/427 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.175); catalogued as rs1389217785, COSV61311921; called by muse, mutect2, varscan2
- OR8K5 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 57/325 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100537127; called by muse, mutect2, varscan2
- PARP2 | c.316C>T p.H106Y | Missense Mutation (SNP) | VAF 40/218 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.345); catalogued as rs761099507, COSV51640007; called by muse, mutect2, varscan2
- PRICKLE2 | c.1320G>T p.Q440H (on ENST00000295902; = p.Q384H on NM_198859.4) | Missense Mutation (SNP) | VAF 102/443 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55770423; called by muse, mutect2, varscan2
- RAB11B | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 52/217 reads (24%) | catalogued as COSV100033165; called by muse, mutect2, varscan2
- RIMS2 | c.1364G>A p.R455Q (on ENST00000666250 / NM_001348490.2; = p.R263Q on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 71/624 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.969); catalogued as COSV51653092; called by muse, mutect2, varscan2
- SCN3A | c.2036C>T p.T679M | Missense Mutation (SNP) | VAF 42/504 reads (8%) | SIFT tolerated (0.13); PolyPhen benign (0.15); catalogued as rs139860168; called by muse, mutect2
- SPEF2 | c.194G>A p.R65H | Missense Mutation (SNP) | VAF 1051/1340 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs772509398, COSV56796785; called by muse, mutect2, varscan2
- SPTA1 | c.2173C>T p.R725* | Nonsense Mutation (SNP) | VAF 105/758 reads (14%) | catalogued as COSV63749301; called by muse, mutect2, varscan2
- TDRD6 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 55/425 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.013); catalogued as rs1347852193; called by muse, mutect2, varscan2
- UHRF1 | c.1648G>A p.A550T (on ENST00000612630 / NM_001290050.1; = p.A563T on NM_013282.4) | Missense Mutation (SNP) | VAF 42/252 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs371287720; called by muse, mutect2, varscan2
- XKR7 | c.1258G>A p.V420I | Missense Mutation (SNP) | VAF 106/670 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.269); catalogued as rs538702175, COSV73813171, COSV73813507; called by muse, mutect2, varscan2
- ZNF407 | c.2549G>A p.R850Q | Missense Mutation (SNP) | VAF 48/255 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.976); catalogued as rs1443295460, COSV55241328, COSV55267207; called by muse, mutect2, varscan2
- ZNF473 | c.2503G>C p.V835L | Missense Mutation (SNP) | VAF 26/456 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.049); catalogued as COSV54522812; called by muse, mutect2
- ADAMTS4 | c.1091G>A p.G364D | Missense Mutation (SNP) | VAF 20/160 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALG8 | c.250T>A p.Y84N | Missense Mutation (SNP) | VAF 53/983 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.601); called by muse, mutect2
- AVL9 | c.470A>G p.Y157C | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- BRSK1 | c.826-5C>A | Splice Region (SNP) | VAF 20/500 reads (4%) | called by muse, mutect2
- C1orf116 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 68/617 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC50 | c.881G>A p.R294K | Missense Mutation (SNP) | VAF 9/228 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.017); called by muse, mutect2
- CDCP1 | c.2017G>T p.A673S | Missense Mutation (SNP) | VAF 44/450 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2
- CSMD1 | c.3838G>T p.G1280C (on ENST00000520002; = p.G1279C on NM_033225.6) | Missense Mutation (SNP) | VAF 12/202 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); called by muse, mutect2
- CXCL1 | c.181A>G p.N61D | Missense Mutation (SNP) | VAF 117/579 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- FANCM | c.2746G>T p.V916F | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.015); called by muse, mutect2
- FAT1 | c.1886C>G p.S629W | Missense Mutation (SNP) | VAF 65/398 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- FZD8 | c.1357T>A p.S453T | Missense Mutation (SNP) | VAF 37/725 reads (5%) | SIFT tolerated (0.91); PolyPhen benign (0.177); called by muse, mutect2
- HEPACAM | c.758T>A p.L253H | Missense Mutation (SNP) | VAF 40/938 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- HNRNPUL1 | c.2165del p.N722Tfs*193 | Frame Shift Del (DEL) | VAF 75/653 reads (11%) | called by mutect2, pindel, varscan2
- HOXB8 | c.277C>T p.R93C | Missense Mutation (SNP) | VAF 193/454 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- INTU | c.2002dup p.T668Nfs*3 | Frame Shift Ins (INS) | VAF 53/337 reads (16%) | called by mutect2, pindel, varscan2
- JUP | c.1874G>A p.G625E | Missense Mutation (SNP) | VAF 43/251 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LMX1A | c.345C>G p.Y115* | Nonsense Mutation (SNP) | VAF 41/700 reads (6%) | called by muse, mutect2
- LRP1B | c.797A>T p.K266I | Missense Mutation (SNP) | VAF 89/282 reads (32%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.606); called by muse, mutect2, varscan2
- LRRC71 | c.488C>T p.P163L | Missense Mutation (SNP) | VAF 108/772 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); called by muse, mutect2, varscan2
- MPHOSPH8 | c.1778A>G p.N593S | Missense Mutation (SNP) | VAF 19/168 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NDST1 | c.232C>T p.P78S | Missense Mutation (SNP) | VAF 58/934 reads (6%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- NOTUM | c.606C>A p.F202L | Missense Mutation (SNP) | VAF 109/460 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NPTXR | c.29C>G p.A10G | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- PCNX1 | c.2020G>A p.A674T | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- PEG3 | c.2512T>G p.L838V | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- PIGW | c.712T>G p.F238V | Missense Mutation (SNP) | VAF 65/211 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PLD1 | c.1216A>G p.K406E | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PRAMEF20 | c.584T>C p.I195T | Missense Mutation (SNP) | VAF 229/1296 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.419); called by muse, mutect2, varscan2
- PRIMPOL | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- PTK7 | c.1613G>A p.R538Q | Missense Mutation (SNP) | VAF 112/296 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.638); called by muse, mutect2, varscan2
- RBM10 | c.663+1G>C p.X221_splice | Splice Site (SNP) | VAF 125/335 reads (37%) | called by muse, mutect2, varscan2
- SEC23IP | c.2765dup p.V923Gfs*3 | Frame Shift Ins (INS) | VAF 30/117 reads (26%) | called by mutect2, pindel, varscan2
- SEMA3F | c.508dup p.T170Nfs*23 | Frame Shift Ins (INS) | VAF 71/540 reads (13%) | called by mutect2, pindel, varscan2
- SLC45A3 | c.1565C>T p.A522V | Missense Mutation (SNP) | VAF 47/440 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.311); called by muse, mutect2, varscan2
- SOWAHB | c.1829T>G p.I610S | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.35); PolyPhen benign (0.006); called by muse, mutect2
- SP4 | c.98A>G p.K33R | Missense Mutation (SNP) | VAF 45/520 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.332); called by muse, mutect2
- SPPL2B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 91/386 reads (24%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TBC1D4 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 176/1079 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- TFAP2C | c.670T>G p.F224V | Missense Mutation (SNP) | VAF 19/412 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- THOP1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.013); called by muse, mutect2
- THSD7B | c.2335T>G p.C779G | Missense Mutation (SNP) | VAF 36/367 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- TP53 | c.632_634del p.T211_F212delinsI | In Frame Del (DEL) | VAF 261/661 reads (39%) | called by mutect2, pindel, varscan2
- ZNF721 | c.2533A>T p.R845* (on ENST00000338977; = p.R857* on NM_133474.4) | Nonsense Mutation (SNP) | VAF 119/580 reads (21%) | called by muse, mutect2, varscan2
- ADGRF2 | c.1248C>A p.S416= (on ENST00000296862 / NM_001368115.2; = p.S348= on NM_153839.7) | Silent (SNP) | VAF 20/312 reads (6%) | catalogued as COSV57289295; called by muse, mutect2
- GDF10 | c.564C>T p.R188= | Silent (SNP) | VAF 40/214 reads (19%) | catalogued as rs781942768; called by muse, mutect2, varscan2
- GPRIN2 | c.825G>T p.G275= | Silent (SNP) | VAF 18/538 reads (3%) | called by muse, mutect2
- MROH7 | c.2316C>G p.L772= | Silent (SNP) | VAF 88/574 reads (15%) | called by muse, mutect2, varscan2
- NMNAT2 | c.135C>T p.G45= | Silent (SNP) | VAF 28/446 reads (6%) | catalogued as rs1166377789, COSV54270332; called by muse, mutect2
- PEG3 | c.1209G>A p.S403= | Silent (SNP) | VAF 77/351 reads (22%) | catalogued as rs751816891, COSV55623768, COSV55626305; called by muse, mutect2, varscan2
- POM121C | c.2823G>A p.P941= (on ENST00000607367; = p.P699= on NM_001099415.3) | Silent (SNP) | VAF 28/504 reads (6%) | catalogued as rs782495998; called by muse, mutect2
- PRDM16 | c.240C>T p.I80= | Silent (SNP) | VAF 35/210 reads (17%) | called by muse, mutect2, varscan2
- ROS1 | c.2859G>A p.E953= | Silent (SNP) | VAF 27/94 reads (29%) | called by muse, mutect2, varscan2
- RUFY2 | c.498C>G p.L166= | Silent (SNP) | VAF 16/223 reads (7%) | catalogued as COSV100700140; called by muse, mutect2
- SI | c.1995C>T p.D665= | Silent (SNP) | VAF 45/274 reads (16%) | catalogued as rs757380218, COSV52272737; called by muse, mutect2, varscan2
- SPEN | c.7992G>A p.P2664= | Silent (SNP) | VAF 95/464 reads (20%) | catalogued as rs757330925; called by muse, mutect2, varscan2
- TLR2 | c.1086A>G p.L362= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as rs765818382; called by muse, mutect2, varscan2
- ZIC1 | c.120C>T p.F40= | Silent (SNP) | VAF 111/641 reads (17%) | catalogued as rs1240281317, COSV51551108; called by muse, mutect2, varscan2
- GRM8 | c.727+48394G>A | Intron (SNP) | VAF 29/196 reads (15%) | catalogued as rs1027479075; called by muse, mutect2, varscan2
- KIF21B | chr1:200973496 C>T | 3'Flank (SNP) | VAF 12/110 reads (11%) | catalogued as rs1246433663; called by muse, mutect2
- MAGEA5 | n.364C>T | RNA (SNP) | VAF 211/342 reads (62%) | called by muse, mutect2, varscan2
- NOC2LP2 | n.553T>C | RNA (SNP) | VAF 210/1072 reads (20%) | called by muse, mutect2, varscan2
- NOVA1 | c.519+66dup | Intron (INS) | VAF 29/191 reads (15%) | called by mutect2, pindel, varscan2
- RGS6 | c.*305A>G | 3'UTR (SNP) | VAF 137/402 reads (34%) | called by muse, mutect2, varscan2
- RHPN1 | c.-54C>G | 5'UTR (SNP) | VAF 23/580 reads (4%) | called by muse, mutect2
